Somatic mutation profile of tumor specimen TCGA-EL-A3CT-01A (aliquot TCGA-EL-A3CT-01A-12D-A202-08) from TCGA case TCGA-EL-A3CT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 78.3 years (28,597 days).
Specimen TCGA-EL-A3CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2e3ad0c-d449-449d-b3a3-793b90bdc793.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CT-10A (Blood Derived Normal), aliquot TCGA-EL-A3CT-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc7f660-2f84-4a9d-9042-66201dd87f1b

The open-access MAF lists 82 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 20, Nonsense Mutation 4, Splice Region 2, 5'Flank 2, 5'UTR 2, Frame Shift Del 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRA1 | c.116A>C p.Y39S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66929743; called by muse, mutect2
- ARFGEF3 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as COSV52458806, COSV99294584; called by muse, mutect2
- ARFIP2 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.129); catalogued as COSV54446937; called by muse, mutect2, varscan2
- ARHGEF18 | c.2965G>A p.V989M (on ENST00000359920 / NM_001130955.2; = p.V885M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750252341, COSV60470282; called by muse, mutect2
- ARSH | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV66963069; called by muse, mutect2, varscan2
- ATM | c.46del p.E16Nfs*18 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as COSV99588815; called by mutect2, pindel, varscan2
- ATP12A | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 104/511 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs149324896; called by muse, mutect2, varscan2
- BICC1 | c.2396C>T p.S799L | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs774773128, COSV54064094; called by muse, mutect2, varscan2
- CBR3 | c.288G>A p.K96= | Splice Region (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51741452; called by muse, mutect2, varscan2
- CCDC6 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs1184010161, COSV54056921; called by muse, mutect2, varscan2
- CLDN6 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs765300431, COSV58509632; called by muse, mutect2, varscan2
- DMTN | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs748096967, COSV56112764; called by muse, mutect2, varscan2
- DTNA | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV51995122, COSV52002591; called by muse, mutect2, varscan2
- EED | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV54555864; called by muse, mutect2, varscan2
- EHBP1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV50421173; called by muse, mutect2, varscan2
- ENOX2 | c.1024G>A p.A342T (on ENST00000338144 / NM_001382520.1; = p.A313T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs749365956, COSV57652229, COSV57655915; called by muse, mutect2
- ERBB3 | c.2303A>G p.H768R | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57254716; called by muse, mutect2, varscan2
- EZR | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61454013; called by muse, mutect2, varscan2
- FAM155A | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV65564369; called by muse, mutect2
- FAM234B | c.1524+1G>A p.X508_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | catalogued as rs780846861, COSV52194909; called by muse, mutect2, varscan2
- FARSA | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1189769005, COSV58903969, COSV58905018; called by muse, mutect2, varscan2
- FIGNL1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 30/149 reads (20%) | catalogued as COSV63553558, COSV63553910; called by muse, mutect2, varscan2
- GFOD1 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV64953201; called by muse, mutect2, varscan2
- GIMAP4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1311447241, COSV55432778; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2
- HNRNPUL2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs372276805, COSV53665174; called by muse, mutect2, varscan2
- IFTAP | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV57557869; called by muse, mutect2, varscan2
- KANSL3 | c.2054C>T p.S685L (on ENST00000666923 / NM_001349262.2; = p.S659L on NM_001115016.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV62618066; called by muse, mutect2, varscan2
- KPNA1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV60269231; called by muse, mutect2, varscan2
- KRT18 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV66316220, COSV66316498; called by muse, mutect2, varscan2
- LONP1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs781065201, COSV62261893; called by muse, mutect2, varscan2
- LRP10 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV62078345; called by muse, mutect2, varscan2
- MBD1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV54001598; called by muse, mutect2, varscan2
- OR5V1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65826589; called by muse, mutect2
- OR8H2 | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV57944950; called by muse, mutect2, varscan2
- PELO | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV50883369; called by muse, mutect2, varscan2
- PI4KB | c.440A>G p.Y147C (on ENST00000368873 / NM_001369623.1; = p.Y159C on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55017832; called by muse, mutect2
- POLB | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV55346809; called by muse, mutect2
- PTCH1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1212879470, COSV59476630; called by muse, mutect2, varscan2
- PTPRZ1 | c.1087T>G p.F363V | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV66437613; called by muse, mutect2, varscan2
- RAB32 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV62249199; called by muse, mutect2
- RCC1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV65779525; called by muse, mutect2, varscan2
- RFX5 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV51839407; called by muse, mutect2, varscan2
- RIC1 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV52610088; called by muse, mutect2, varscan2
- RPRD1A | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1447718530, COSV59822149; called by muse, mutect2, varscan2
- SPDYA | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61856032; called by muse, mutect2, varscan2
- TMEM50B | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70279113, COSV70279332; called by muse, mutect2
- TOMM20L | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs761657991, COSV62878299; called by muse, mutect2, varscan2
- TP73 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV60702112; called by muse, mutect2
- WWC1 | c.2826G>A p.L942= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as rs771762858, COSV54651639; called by muse, mutect2, varscan2
- YES1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV58850437; called by muse, mutect2, varscan2
- ZNF646 | c.1823A>C p.E608A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV56214932; called by muse, mutect2, varscan2
- ZNF721 | c.2594C>T p.S865F (on ENST00000338977; = p.S877F on NM_133474.4) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.485); catalogued as COSV59093194; called by muse, mutect2, varscan2
- CBWD3 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZC3H18 | c.1817del p.P606Rfs*32 | Frame Shift Del (DEL) | VAF 23/143 reads (16%) | called by mutect2, pindel, varscan2
- ADGRE3 | c.1848C>T p.I616= | Silent (SNP) | VAF 22/227 reads (10%) | catalogued as rs147270469, COSV53729101; called by muse, mutect2
- AHNAK | c.1954C>T p.L652= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as COSV57215374; called by muse, mutect2, varscan2
- ALG3 | c.33C>T p.S11= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs752859572, COSV100200966; called by muse, varscan2
- CDK5 | c.294C>T p.L98= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV52522816; called by muse, mutect2, varscan2
- DENND6B | c.1116G>A p.L372= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV69807022; called by muse, mutect2, varscan2
- DPP3 | c.1614G>A p.V538= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV64756928; called by muse, mutect2, varscan2
- DUSP6 | c.231C>T p.F77= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1380245708, COSV54378066; called by muse, mutect2, varscan2
- GLCE | c.1740C>T p.T580= | Silent (SNP) | VAF 81/334 reads (24%) | catalogued as COSV55946130; called by muse, mutect2, varscan2
- H3C6 | c.375C>T p.I125= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as rs1305009188, COSV64519624; called by muse, mutect2, varscan2
- ICAM1 | c.51C>T p.L17= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV53425274; called by muse, mutect2
- ICAM1 | c.1446C>T p.V482= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs771104368, COSV53425283; called by muse, mutect2, varscan2
- KCNV2 | c.1128G>A p.L376= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs780625453, COSV66056341; called by muse, mutect2, varscan2
- LAMB2 | c.210G>A p.L70= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV59734042; called by muse, varscan2
- NAAA | c.201C>T p.V67= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs751752521, COSV54432434; called by muse, mutect2, varscan2
- NOL4 | c.1719C>T p.S573= | Silent (SNP) | VAF 38/211 reads (18%) | catalogued as COSV52348505; called by muse, mutect2, varscan2
- OR4K17 | c.801A>T p.V267= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV59648255; called by muse, mutect2, varscan2
- PCDHGA12 | c.78C>T p.T26= | Silent (SNP) | VAF 11/240 reads (5%) | catalogued as rs1350348914, COSV52753849; called by muse, mutect2
- POU5F1 | c.537C>T p.F179= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52563861; called by muse, mutect2
- TMEM63A | c.2103C>T p.F701= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55301177; called by muse, mutect2
- ZNF556 | c.858G>A p.P286= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs377206346; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498499 C>T | 5'Flank (SNP) | VAF 15/62 reads (24%) | catalogued as rs778788807; called by muse, mutect2, varscan2
- ATP6V1G2 | chr6:31548264 C>T | 5'Flank (SNP) | VAF 23/88 reads (26%) | catalogued as COSV58214656; called by muse, mutect2, varscan2
- ATP7B | c.-1G>A | 5'UTR (SNP) | VAF 19/109 reads (17%) | catalogued as COSV99666073; called by muse, mutect2, varscan2
- SNORD3B-1 | n.166G>A | RNA (SNP) | VAF 28/334 reads (8%) | catalogued as rs763079501; called by muse, varscan2
- SNORD3B-2 | n.159G>A | RNA (SNP) | VAF 37/332 reads (11%) | catalogued as rs763526532; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 16/48 reads (33%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
